CCDI case PBBYCL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/522d2217-3cf3-44f9-abc6-62dcdb7c2210

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,459 days).

Biospecimens (2 samples)
- Sample 0DKDC1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKDDD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
